Somatic mutation profile of tumor specimen TARGET-20-PARLVL-09A (aliquot TARGET-20-PARLVL-09A-01D) from TARGET case TARGET-20-PARLVL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (963 days).
Specimen TARGET-20-PARLVL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b1f16b0-35fd-49bf-befd-44a8c7f5e6f3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARLVL-14A (Bone Marrow Normal), aliquot TARGET-20-PARLVL-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fecaaef1-cc3f-4387-b96e-9b525a27d505

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 63/121 reads (52%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- EP300 | c.3671+1del p.X1224_splice | Splice Site (DEL) | VAF 34/132 reads (26%) | catalogued as COSV54327591, COSV99607896; called by mutect2, pindel, varscan2
- FLT3 | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV54047457, COSV54049031, COSV54049919; called by muse, mutect2
- GATA2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1420609104, CM141457, COSV62005311; called by muse, mutect2
- WT1 | c.708del p.S238Rfs*53 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | catalogued as COSV60070198; called by mutect2, pindel, varscan2
